Surgical pathology report (de-identified scan), TCGA case TCGA-K1-A3PN, project TCGA-SARC (Sarcoma), tissue source site University of Pittsburgh, specimen TCGA-K1-A3PN-02A (Recurrent Tumor).

FINAL DIAGNOSIS:

PART 1: SKIN AND SOFT TISSUE, ABDOMINAL WALL, EXCISIONAL BIOPSY -

- A. RECURRENT LEIOMYOSARCOMA, SEE PRIOR (see comment). Collection Date:
- B. MARGINS OF RESECTION ARE FREE OF TUMOR.
- C. SKIN WITH SCAR.
- D. FAT NECROSIS AND CHANGES CONSISTENT WITH PREVIOUS CORE BIOPSY SITE, SEE PRIOR

PART 2: FACIAL MARGIN, EXCISION -

FIBROVASCULAR ADIPOSE TISSUE, NO TUMOR IS SEEN.

COMMENT:

Part 1: This recurrent leiomyosarcoma depicts severe cytologic atypia with necrosis and mitoses ranging from 10-24/10 high-powered fields. The tumor comes to within 2 mm from the nearest inked resection margin (1C).

ICD-0-3

Leiomyosarcoma 8890/3
NOS

Site: abdominal wall C49.4

hw
11/7/14

Recurrence

Source: NCI Genomic Data Commons file fcbbfcbe-9dcd-419d-90a2-b24d4ab3a4ee (TCGA-K1-A3PN.B1128047-E18A-499C-B230-88EC38DFAB2C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).